Somatic mutation profile of tumor specimen TCGA-BJ-A2NA-01A (aliquot TCGA-BJ-A2NA-01A-12D-A19J-08) from TCGA case TCGA-BJ-A2NA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 77.1 years (28,147 days).
Specimen TCGA-BJ-A2NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08f59825-d3c5-48c3-a54d-1e0ceb331604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A2NA-10A (Blood Derived Normal), aliquot TCGA-BJ-A2NA-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1ab5bc0-f20d-4539-bfe9-c8e9bc57ec98

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 21, Silent 14, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA9 | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100382494; called by muse, mutect2
- ABHD2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV61774219; called by muse, mutect2, varscan2
- ATG14 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV55956694; called by muse, mutect2, varscan2
- CNTRL | c.6740G>A p.R2247Q | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs764334541, COSV53047577; called by muse, mutect2, varscan2
- CREB3L3 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as rs201474344; called by muse, mutect2, varscan2
- CYC1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV59645479; called by muse, mutect2, varscan2
- FA2H | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs779374650, COSV54726385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF22 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV60034690; called by muse, mutect2
- KHNYN | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52160688; called by muse, mutect2, varscan2
- MRS2 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV51234468; called by muse, mutect2
- NKX2-1 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100701975, COSV61388719; called by muse, mutect2
- NSD3 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.143); catalogued as rs775297532, COSV57619023; called by muse, mutect2, varscan2
- OR2C1 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59240367; called by muse, mutect2, varscan2
- PHF23 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as COSV50036136; called by muse, mutect2, varscan2
- PIBF1 | c.1842A>C p.R614S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.23); catalogued as COSV58323377; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1008del p.M336Ifs*10 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as COSV62926248; called by mutect2, pindel, varscan2
- RASD2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352583; called by muse, mutect2
- SLC34A2 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV65941643; called by muse, mutect2, varscan2
- SLC39A2 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180668026, COSV53869678; called by muse, mutect2, varscan2
- TTBK2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51162008; called by muse, mutect2, varscan2
- TYMP | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.192); catalogued as COSV52687989, COSV52688518; called by muse, mutect2, varscan2
- UNC13A | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53196822; called by muse, mutect2
- ZSCAN5B | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV62000253; called by muse, mutect2, varscan2
- KIAA0319L | c.2346G>A p.V782= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV57846008; called by muse, mutect2, varscan2
- MDN1 | c.10674G>A p.R3558= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV65522282; called by muse, varscan2
- MYF5 | c.591T>C p.D197= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV57355269; called by muse, mutect2, varscan2
- OR10Q1 | c.819G>A p.E273= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs746131960, COSV57470598, COSV57471953; called by muse, mutect2, varscan2
- PHF23 | c.399C>G p.L133= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV50036138; called by muse, mutect2, varscan2
- PNCK | c.258C>T p.L86= (on ENST00000340888 / NM_001366975.1; = p.L169= on NM_001039582.3) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61743956; called by muse, mutect2, varscan2
- PPFIA3 | c.2964C>T p.N988= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV53256388; called by muse, mutect2, varscan2
- PPP1R14C | c.246G>T p.R82= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV63174217; called by muse, mutect2, varscan2
- SNX31 | c.99C>T p.F33= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV61261814, COSV61263256; called by muse, mutect2
- ST8SIA1 | c.99T>C p.S33= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV53954283; called by muse, mutect2, varscan2
- SUPT20H | c.45C>T p.V15= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV62248032; called by muse, mutect2, varscan2
- SWSAP1 | c.192C>A p.I64= (on ENST00000312423; = p.I85= on NM_175871.4) | Silent (SNP) | VAF 93/250 reads (37%) | catalogued as COSV55800384; called by muse, mutect2, varscan2
- TAF7L | c.180C>T p.D60= | Silent (SNP) | VAF 72/103 reads (70%) | catalogued as COSV63300051; called by muse, mutect2, varscan2
- ZDHHC14 | c.186C>T p.G62= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs765067657, COSV63070593, COSV63072147; called by muse, mutect2, varscan2
